Somatic mutation profile of tumor specimen ALCH-B1IQ-TTP1-A (aliquot ALCH-B1IQ-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1IQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.9 years (25,883 days).
Specimen ALCH-B1IQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f70de0cf-e09c-4b9b-9ffb-559a84f8dde3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1IQ-NB1-A (Blood Derived Normal), aliquot ALCH-B1IQ-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15fa8002-cbbe-4394-b7bd-fb10c405ebc7

The open-access MAF lists 482 somatic variants for this specimen: 309 protein-altering or splice-affecting, 96 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 252, Silent 96, Intron 36, Nonsense Mutation 22, Frame Shift Del 19, RNA 17, 3'UTR 11, Splice Site 9, 5'UTR 7, Frame Shift Ins 5, 5'Flank 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4397G>T p.W1466L | Missense Mutation (SNP) | VAF 110/602 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54329712, COSV54343301, COSV54343868; called by mutect2, varscan2
- PTEN | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as rs869312778, COSV64294055, COSV64304098; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 71/280 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACP7 | c.692+8G>T | Splice Region (SNP) | VAF 34/284 reads (12%) | catalogued as rs1352653157; called by muse, mutect2, varscan2
- ADAMTS20 | c.5406C>G p.F1802L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101239754; called by muse, mutect2
- AHNAK | c.7716G>T p.M2572I | Missense Mutation (SNP) | VAF 73/436 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as COSV57204418; called by muse, mutect2, varscan2
- ANK1 | c.852C>G p.H284Q | Missense Mutation (SNP) | VAF 182/928 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55875887; called by muse, mutect2, varscan2
- AOAH | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.037); catalogued as COSV99332539; called by muse, mutect2, varscan2
- BTBD6 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV59267923; called by muse, mutect2, varscan2
- C20orf85 | c.275del p.P92Hfs*17 | Frame Shift Del (DEL) | VAF 49/205 reads (24%) | catalogued as COSV64519869; called by mutect2, pindel, varscan2
- C2orf16 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.204); catalogued as rs962328164; called by muse, mutect2, varscan2
- CD180 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56519792; called by muse, mutect2, varscan2
- CDH8 | c.1675G>T p.A559S | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs1342737596; called by muse, varscan2
- CSMD3 | c.7682G>T p.R2561L (on ENST00000297405 / NM_001363185.1; = p.R2457L on NM_052900.3) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs750618214, COSV52169321, COSV52276730; called by muse, mutect2, varscan2
- CSMD3 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52121622; called by muse, varscan2
- DDX1 | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs1241237908; called by muse, mutect2, varscan2
- DGAT2 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 97/547 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57177581; called by muse, mutect2, varscan2
- ERBIN | c.58del p.E20Kfs*15 | Frame Shift Del (DEL) | VAF 57/255 reads (22%) | catalogued as COSV52323326; called by mutect2, pindel, varscan2
- FAM111A | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64655282; called by muse, mutect2, varscan2
- FAM122B | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53230518; called by muse, mutect2, varscan2
- FAM47A | c.1402del p.L468Cfs*113 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as COSV60499929; called by mutect2, pindel, varscan2
- FAM47B | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 134/722 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs202142258, COSV61456638; called by muse, mutect2, varscan2
- FAM47C | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs868925278, COSV100792975, COSV63728294; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | catalogued as rs752076602; called by mutect2, pindel
- FREM3 | c.3673C>A p.P1225T | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV61680927; called by muse, mutect2, varscan2
- GAD1 | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 97/531 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs1265179873; called by muse, mutect2, varscan2
- GALNT17 | c.1637G>C p.S546T | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs765359078, COSV61182224, COSV61187861; called by muse, mutect2, varscan2
- HLA-A | c.470G>C p.W157S | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs199474533, CM1412085; called by muse, mutect2
- HNF1A | c.410C>G p.T137S | Missense Mutation (SNP) | VAF 96/602 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as CM082808; called by muse, mutect2, varscan2
- HTT | c.4633A>G p.I1545V | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.978); catalogued as rs1372380539; called by muse, mutect2, varscan2
- IL22 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs972924631, COSV100048824; called by muse, mutect2, varscan2
- ING1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs566251972; called by muse, mutect2, varscan2
- ITIH6 | c.3458G>T p.R1153L | Missense Mutation (SNP) | VAF 68/469 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99513752; called by muse, mutect2, varscan2
- KCNT1 | c.3424G>A p.E1142K (on ENST00000488444; = p.D1168N on NM_020822.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs747317425, COSV53707605, COSV53711347; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KIAA1755 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54075292; called by muse, mutect2, varscan2
- KRT73 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 79/429 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59841320; called by muse, mutect2, varscan2
- LAMA4 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 91/518 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV100038409; called by muse, mutect2, varscan2
- LAS1L | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 81/648 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100408522; called by muse, mutect2, varscan2
- MECOM | c.3142A>G p.I1048V (on ENST00000468789 / NM_001105078.4; = p.I1236V on NM_004991.4) | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs757625757, COSV52961875; called by muse, mutect2, varscan2
- MPIG6B | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.653); catalogued as rs985453732, COSV65390405; called by muse, mutect2, varscan2
- MUC17 | c.9604A>G p.T3202A | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV60279859; called by muse, mutect2, varscan2
- NCOA2 | c.1081A>T p.T361S | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV71763753; called by muse, mutect2, varscan2
- NCR2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 115/550 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs866579344; called by muse, mutect2, varscan2
- NDN | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59358224; called by muse, mutect2, varscan2
- NF1 | c.244_247del p.Q83* | Frame Shift Del (DEL) | VAF 23/172 reads (13%) | catalogued as rs771115661; called by mutect2, pindel
- NPHS1 | c.2882G>A p.W961* | Nonsense Mutation (SNP) | VAF 48/295 reads (16%) | catalogued as rs1202202990; called by muse, mutect2, varscan2
- ONECUT1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767975108, COSV59950547; called by muse, mutect2, varscan2
- OR2L2 | c.143T>A p.I48N | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746504289; called by muse, mutect2, varscan2
- OR2M5 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV63546511; called by muse, mutect2, varscan2
- OR51G1 | c.623C>G p.T208S | Missense Mutation (SNP) | VAF 124/830 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58968533; called by muse, mutect2, varscan2
- OR6C2 | c.832T>A p.S278T | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100498670; called by muse, mutect2, varscan2
- OR8H2 | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.4); catalogued as COSV57943765; called by muse, mutect2, varscan2
- OSCAR | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as rs1282620345; called by muse, mutect2, varscan2
- PABPC1L | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369260391; called by muse, mutect2, varscan2
- PCDHGB3 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as rs780330964; called by muse, mutect2, varscan2
- PHKA1 | c.1180C>G p.P394A | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.26); catalogued as COSV100263749; called by muse, mutect2, varscan2
- PIGR | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV62904085; called by muse, mutect2, varscan2
- PKDREJ | c.2012C>G p.T671S | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV53554646; called by muse, mutect2, varscan2
- POLD3 | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs377052981; called by muse, mutect2, varscan2
- POMC | c.516C>A p.F172L | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs770388153; called by muse, mutect2, varscan2
- PTCHD1 | c.1700G>A p.W567* | Nonsense Mutation (SNP) | VAF 82/370 reads (22%) | catalogued as COSV101037227; called by muse, mutect2, varscan2
- PTPRO | c.1952G>C p.W651S | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99841538; called by muse, mutect2, varscan2
- RGPD8 | c.2648A>G p.Y883C | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs778941648; called by muse, mutect2, varscan2
- RIMBP2 | c.2614G>T p.E872* | Nonsense Mutation (SNP) | VAF 65/363 reads (18%) | catalogued as COSV99898480; called by muse, mutect2, varscan2
- RIMS1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 104/558 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53436901; called by muse, mutect2, varscan2
- RIMS1 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV53456616; called by muse, varscan2
- RNF157 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 101/569 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350560949, COSV53943555, COSV99487190; called by muse, mutect2, varscan2
- RNF31 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs775187700; called by muse, mutect2, varscan2
- SF3A2 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.175); catalogued as rs745992454; called by muse, mutect2, varscan2
- SHROOM4 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 162/705 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs782624710; called by muse, mutect2, varscan2
- SLC25A22 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1468529315; called by muse, mutect2, varscan2
- SLC26A11 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs370455417; called by muse, mutect2, varscan2
- SLC44A1 | c.761-1G>C p.X254_splice | Splice Site (SNP) | VAF 61/329 reads (19%) | catalogued as COSV58265339; called by muse, mutect2, varscan2
- SPANXN2 | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); catalogued as COSV65129427; called by muse, varscan2
- SPATC1L | c.779G>T p.R260L (on ENST00000291672 / NM_001142854.2; = p.R106L on NM_032261.5) | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.195); catalogued as rs373386591; called by muse, mutect2, varscan2
- SSH1 | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV100425324; called by muse, mutect2, varscan2
- SUZ12 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 33/221 reads (15%) | catalogued as COSV100496750; called by muse, mutect2, varscan2
- TAF3 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV60206510; called by muse, mutect2, varscan2
- TAF5L | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99272949; called by muse, mutect2, varscan2
- TARBP1 | c.2431A>G p.S811G | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs1476018521; called by muse, mutect2, varscan2
- TDRD5 | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as COSV54248620; called by muse, mutect2, varscan2
- TECR | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 107/569 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs750628073, COSV53109023; called by muse, mutect2, varscan2
- TGM6 | c.1894del p.L632Sfs*2 | Frame Shift Del (DEL) | VAF 100/527 reads (19%) | catalogued as COSV52483830; called by mutect2, pindel, varscan2
- TMEM202 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs781115254; called by muse, mutect2, varscan2
- TNR | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54876334; called by muse, mutect2, varscan2
- TRDN | c.1744G>C p.A582P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV62125386; called by muse, varscan2
- TYR | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD045350; called by muse, mutect2, varscan2
- UFL1 | c.1657T>A p.L553I | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100990122; called by muse, mutect2
- UTRN | c.4705C>T p.Q1569* | Nonsense Mutation (SNP) | VAF 30/201 reads (15%) | catalogued as rs1202445608; called by muse, mutect2, varscan2
- XCR1 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 107/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1412892725; called by muse, mutect2, varscan2
- ZDHHC12 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV52580385; called by muse, mutect2, varscan2
- ZNF761 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs758831420; called by muse, mutect2, varscan2
- ZNF835 | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.122); catalogued as rs1014428820; called by muse, mutect2, varscan2
- ZNF853 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1303488580, COSV101499522; called by muse, mutect2, varscan2
- ZPBP | c.550A>G p.S184G | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.626); catalogued as rs1299521157, CM118239; called by muse, mutect2, varscan2
- ABCC12 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ACER1 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSS3 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAT1 | c.1258A>T p.T420S | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADGRL3 | c.1293C>G p.Y431* (on ENST00000506720 / NM_001322402.2; = p.Y363* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | called by muse, varscan2
- ADGRL3 | c.3208G>C p.D1070H (on ENST00000506720 / NM_001322402.2; = p.D1002H on NM_015236.6) | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- AKAP1 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ALDH1L1 | c.1618A>T p.I540F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX4 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ANKRD30B | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ARRDC2 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ARV1 | c.132G>C p.L44F | Missense Mutation (SNP) | VAF 107/656 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASCL4 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPG | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ASPM | c.9085-2A>G p.X3029_splice | Splice Site (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- ATP8B2 | c.998A>T p.H333L (on ENST00000672630; = p.H300L on NM_001005855.2) | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAAT | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEST2 | c.673T>G p.F225V | Missense Mutation (SNP) | VAF 53/413 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- BTG3 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BUD13 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 127/655 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf15 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CA5A | c.774+1G>T p.X258_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2
- CACNA2D3 | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CATSPER3 | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CAVIN3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC183 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC85B | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CCNB3 | c.3378C>A p.N1126K | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CD40 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 91/623 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CDK18 | c.954G>T p.R318S (on ENST00000506784 / NM_212503.3; = p.R288S on NM_002596.4) | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CELF4 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CFAP61 | c.2263G>T p.V755L | Missense Mutation (SNP) | VAF 96/550 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMKLR1 | c.542C>T p.A181V (on ENST00000312143 / NM_001142344.2; = p.A179V on NM_004072.3) | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CNDP2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- COL11A1 | c.3191C>G p.S1064* | Nonsense Mutation (SNP) | VAF 45/312 reads (14%) | called by muse, mutect2, varscan2
- COL22A1 | c.4648C>A p.P1550T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- COL4A6 | c.1352A>T p.H451L | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A2 | c.3432C>A p.H1144Q | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL8A1 | c.1490del p.P497Qfs*36 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- CSE1L | c.665T>C p.L222S | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CST9L | c.359T>C p.F120S | Missense Mutation (SNP) | VAF 107/482 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CYBB | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 71/463 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DARS2 | c.8T>G p.F3C | Missense Mutation (SNP) | VAF 177/1098 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DNAH10 | c.9661C>A p.P3221T (on ENST00000409039; = p.P3160T on NM_207437.3) | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH10 | c.10103A>G p.Q3368R (on ENST00000409039; = p.Q3307R on NM_207437.3) | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- DNAH12 | c.3534G>T p.M1178I (on ENST00000351747; = p.M1201I on NM_001366028.2) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, varscan2
- DNAH5 | c.13338A>T p.K4446N | Missense Mutation (SNP) | VAF 109/691 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DNAJC1 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 71/401 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNER | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOK7 | c.246C>A p.C82* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- DSPP | c.3860G>A p.S1287N | Missense Mutation (SNP) | VAF 164/836 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DTX3L | c.400-1G>T p.X134_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | called by muse, varscan2
- DUSP15 | c.166C>A p.P56T (on ENST00000278979 / NM_001320479.1; = p.P59T on NM_080611.4) | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DVL3 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EGFR | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 147/663 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ELK1 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ERICH3 | c.2901G>T p.E967D | Missense Mutation (SNP) | VAF 97/672 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ERN2 | c.1459A>T p.S487C | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- EVC2 | c.1891G>T p.G631W | Missense Mutation (SNP) | VAF 81/487 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F11 | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 124/549 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F13A1 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAP | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FGL1 | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 98/447 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FITM1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXG1 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 97/547 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAREM2 | c.780del p.V261* | Frame Shift Del (DEL) | VAF 34/206 reads (17%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.1793A>G p.Q598R | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNAT3 | c.957T>G p.I319M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- GPR119 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- GPR32 | c.936delinsAA p.N312Kfs*? | Frame Shift Ins (INS) | VAF 40/428 reads (9%) | called by pindel, varscan2*
- GSDMC | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- GTPBP4 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 47/488 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HCCS | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 71/456 reads (16%) | called by muse, mutect2, varscan2
- HDAC6 | c.1944G>A p.W648* | Nonsense Mutation (SNP) | VAF 64/402 reads (16%) | called by muse, mutect2, varscan2
- HECW2 | c.1640C>A p.P547Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPC | c.742A>T p.N248Y (on ENST00000420743; = p.N235Y on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXC4 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD10 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 90/483 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSH2D | c.938T>A p.V313E | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HSPB6 | c.141del p.T48Pfs*31 | Frame Shift Del (DEL) | VAF 25/158 reads (16%) | called by mutect2, pindel, varscan2
- ICAM4 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 95/535 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IDS | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 88/574 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- IFT52 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- IGHV3-23 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2
- IGSF5 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 115/425 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL25 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 135/578 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ISM1 | c.1302C>G p.N434K | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ITGAM | c.3172A>G p.I1058V (on ENST00000648685 / NM_001145808.2; = p.I1057V on NM_000632.4) | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- JMJD1C | c.6077-5_6082del p.X2026_splice | Splice Site (DEL) | VAF 30/146 reads (21%) | called by mutect2, pindel
- JMJD7-PLA2G4B | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KAT6A | c.5323C>T p.P1775S | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- KDM1B | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- KIAA1217 | c.2393A>G p.H798R | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLHL13 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- LRCH2 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, varscan2
- LRP2 | c.8289C>A p.Y2763* | Nonsense Mutation (SNP) | VAF 78/565 reads (14%) | called by muse, mutect2, varscan2
- MAGEB18 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAGEB4 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC1 | c.3281C>A p.T1094N | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, varscan2
- MAP2K5 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MOCS1 | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 122/597 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MOG | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 191/1046 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPL | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- MRGPRX3 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 80/519 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MROH2B | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MS4A12 | c.328T>A p.C110S | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC19 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MYH7 | c.3825C>A p.S1275R | Missense Mutation (SNP) | VAF 190/919 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MYO1C | c.637G>T p.V213L (on ENST00000648651 / NM_001080779.2; = p.V178L on NM_033375.5) | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MYO7B | c.6129+2T>A p.X2043_splice | Splice Site (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- MYOM3 | c.3329A>T p.K1110M | Missense Mutation (SNP) | VAF 63/416 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NANOS3 | c.97del p.Q33Sfs*44 (on ENST00000397555; = p.Q33Sfs*63 on NM_001098622.2) | Frame Shift Del (DEL) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- NCOA6 | c.6172A>T p.K2058* | Nonsense Mutation (SNP) | VAF 77/374 reads (21%) | called by muse, mutect2, varscan2
- NELL1 | c.2121C>A p.D707E | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- NF1 | c.1674_1681del p.I558Mfs*4 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | called by mutect2, pindel
- NIPAL3 | c.730del p.V244* | Frame Shift Del (DEL) | VAF 60/404 reads (15%) | called by mutect2, pindel, varscan2
- NLRP6 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NOVA1 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NPAP1 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NXF3 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ONECUT1 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- OR10G8 | c.499T>A p.Y167N | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR11H4 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OR2L5 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- OR2T3 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 48/836 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2
- OR2T6 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- OR4K1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ORC5 | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- OTOGL | c.2995T>C p.C999R (on ENST00000547103; = p.C990R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OTUD5 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PCDHB6 | c.2145C>G p.S715R | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDHA1 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 77/500 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDK3 | c.881T>A p.L294H | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PGAM4 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 117/705 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PHF21A | c.1076G>T p.R359L (on ENST00000418153 / NM_001101802.3; = p.R360L on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PLCH2 | c.1687G>T p.G563W | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PLCZ1 | c.1539dup p.G514Wfs*5 | Frame Shift Ins (INS) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- PLEC | c.8310dup p.D2771* (on ENST00000322810 / NM_201380.4; = p.D2661* on NM_000445.5) | Frame Shift Ins (INS) | VAF 55/338 reads (16%) | called by mutect2, pindel, varscan2
- PLEKHG5 | c.3034G>T p.G1012W (on ENST00000400915 / NM_001042663.3; = p.G975W on NM_020631.6) | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PNPLA8 | c.1518T>G p.Y506* | Nonsense Mutation (SNP) | VAF 38/238 reads (16%) | called by muse, varscan2
- POTEC | c.1242+1G>C p.X414_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- PRDM15 | c.3440dup p.T1148Dfs*15 | Frame Shift Ins (INS) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- PRICKLE3 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCG | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCG | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 71/501 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRR36 | c.1161del p.S388Lfs*15 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- PUS7 | c.1436A>T p.Y479F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD9A | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASA1 | c.806_810del p.L269Pfs*11 | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | called by pindel, varscan2
- RBM25 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.6388C>G p.P2130A | Missense Mutation (SNP) | VAF 125/642 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- RELN | c.1623del p.R541Sfs*15 | Frame Shift Del (DEL) | VAF 48/312 reads (15%) | called by pindel, varscan2
- REV1 | c.988_991del p.S330Rfs*38 | Frame Shift Del (DEL) | VAF 30/280 reads (11%) | called by pindel, varscan2
- RHOXF2B | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 128/860 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.672); called by muse, varscan2
- RIN2 | c.685del p.X229_splice (on ENST00000255006 / NM_001242581.1; = p.X180_splice on NM_018993.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 59/364 reads (16%) | called by mutect2, pindel, varscan2
- RP1 | c.3113G>C p.C1038S | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RSPH3 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTTN | c.6321G>T p.E2107D | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SALL1 | c.2033G>C p.G678A | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SBNO2 | c.2874C>G p.D958E | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SFPQ | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2
- SIRPB1 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SLC12A4 | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC1A3 | c.1187C>A p.T396N | Missense Mutation (SNP) | VAF 98/562 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A48 | c.914A>T p.D305V (on ENST00000650267; = p.T255S on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC30A10 | c.1136C>A p.T379N | Missense Mutation (SNP) | VAF 115/649 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC30A10 | c.278G>A p.C93Y | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SLITRK3 | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SOX5 | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SP100 | c.2058A>G p.I686M | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SPRED3 | c.495del p.I166Sfs*82 | Frame Shift Del (DEL) | VAF 19/150 reads (13%) | called by mutect2, pindel, varscan2
- SPSB4 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SRCAP | c.5536G>T p.D1846Y | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SRSF11 | c.1325_1326insC p.K442Nfs*10 | Frame Shift Ins (INS) | VAF 26/184 reads (14%) | called by mutect2, pindel*, varscan2
- STAB2 | c.4265G>A p.W1422* | Nonsense Mutation (SNP) | VAF 55/378 reads (15%) | called by muse, mutect2, varscan2
- STIM1 | c.166T>A p.C56S | Missense Mutation (SNP) | VAF 107/579 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- STK19 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SUPT5H | c.2723C>A p.P908H | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SUPT6H | c.2619G>T p.Q873H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SUPT6H | c.2620G>T p.G874C | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SUZ12 | c.1161G>T p.Q387H | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.256A>T p.N86Y | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYNGR1 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAAR6 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TCF23 | c.380A>T p.H127L | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- TDRD1 | c.1804A>G p.M602V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TECPR1 | c.3220G>T p.V1074L | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TENM1 | c.3185T>C p.V1062A | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TESPA1 | c.1501A>T p.S501C (on ENST00000316577 / NM_001098815.3; = p.S363C on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TEX13C | c.2417C>A p.A806D | Missense Mutation (SNP) | VAF 79/397 reads (20%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- TMEM209 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 72/439 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- TMEM232 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFRSF13B | c.456del p.L153* | Frame Shift Del (DEL) | VAF 76/336 reads (23%) | called by mutect2, pindel, varscan2
- TOR2A | c.436del p.V146Sfs*25 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- TRIM51 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 54/577 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, varscan2
- TRIM77 | c.1010G>C p.S337T | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP12 | c.2848G>T p.G950* | Nonsense Mutation (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.31120G>T p.A10374S (on ENST00000591111; = p.A9447S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/284 reads (9%) | PolyPhen benign (0.001); called by muse, mutect2
- USH2A | c.13466G>T p.G4489V | Missense Mutation (SNP) | VAF 61/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP46 | c.506A>T p.H169L | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WDFY4 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.272); called by muse, varscan2
- XIRP2 | c.2227A>T p.T743S (on ENST00000628543; = p.T918S on NM_152381.6) | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XKR3 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.486); called by muse, varscan2
- XPNPEP2 | c.1295+1G>T p.X432_splice | Splice Site (SNP) | VAF 81/477 reads (17%) | called by muse, mutect2, varscan2
- XPO1 | c.1615A>T p.I539F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZFHX4 | c.1952G>A p.W651* | Nonsense Mutation (SNP) | VAF 134/439 reads (31%) | called by muse, mutect2, varscan2
- ZFYVE21 | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF354B | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, varscan2
- ZNF485 | c.640C>A p.H214N | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ZNF507 | c.1117A>T p.I373F | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF600 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ZNF729 | c.3466G>C p.V1156L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, varscan2
- ZNF98 | c.7G>T p.G3* | Nonsense Mutation (SNP) | VAF 64/387 reads (17%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.033); called by muse, mutect2
- ADAM12 | c.1771C>A p.R591= | Silent (SNP) | VAF 99/390 reads (25%) | catalogued as COSV64114150; called by muse, mutect2, varscan2
- ADAMTS13 | c.1035C>T p.S345= | Silent (SNP) | VAF 121/498 reads (24%) | called by muse, mutect2, varscan2
- ADRB3 | c.954G>T p.G318= | Silent (SNP) | VAF 223/700 reads (32%) | called by muse, mutect2, varscan2
- AP2A1 | c.1758C>T p.L586= | Silent (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- AQP8 | c.723T>C p.V241= | Silent (SNP) | VAF 44/170 reads (26%) | called by muse, mutect2, varscan2
- ASB18 | c.409C>A p.R137= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as rs1400355308; called by muse, mutect2, varscan2
- C6 | c.363G>T p.L121= | Silent (SNP) | VAF 61/462 reads (13%) | catalogued as COSV54704513; called by muse, mutect2, varscan2
- CDH13 | c.252G>T p.L84= | Silent (SNP) | VAF 53/458 reads (12%) | called by muse, mutect2, varscan2
- CDH16 | c.1554C>T p.L518= | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- CEBPZ | c.1566C>T p.T522= | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- CFH | c.3027G>A p.K1009= | Silent (SNP) | VAF 67/488 reads (14%) | called by muse, mutect2, varscan2
- CHIA | c.714C>T p.N238= (on ENST00000343320; = p.N130= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as rs139759326; called by muse, mutect2, varscan2
- CRYBA4 | c.426C>T p.F142= | Silent (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- DMAP1 | c.1107C>T p.S369= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs752229758, COSV59999960, COSV59999988; called by muse, mutect2, varscan2
- DTD1 | c.261G>A p.K87= | Silent (SNP) | VAF 84/393 reads (21%) | catalogued as COSV101079869; called by muse, mutect2, varscan2
- EPB41 | c.1927C>T p.L643= (on ENST00000343067 / NM_001166005.2; = p.L434= on NM_203342.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, varscan2
- ERCC5 | c.15G>T p.G5= | Silent (SNP) | VAF 61/241 reads (25%) | called by muse, mutect2, varscan2
- FAM135B | c.4113C>A p.P1371= | Silent (SNP) | VAF 134/960 reads (14%) | catalogued as COSV52710339, COSV99422391; called by muse, mutect2, varscan2
- FANCA | c.2874G>T p.A958= | Silent (SNP) | VAF 114/519 reads (22%) | catalogued as rs199916178; called by muse, mutect2, varscan2
- FBF1 | c.1050C>T p.D350= (on ENST00000586717; = p.D364= on NM_001319193.1) | Silent (SNP) | VAF 71/330 reads (22%) | catalogued as rs541926169, COSV59863861; called by muse, mutect2, varscan2
- GNAT3 | c.987C>T p.T329= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs1311832665; called by muse, varscan2
- GNL3L | c.300G>A p.E100= | Silent (SNP) | VAF 36/254 reads (14%) | called by muse, mutect2, varscan2
- GPRASP1 | c.1806C>A p.T602= | Silent (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- GPRASP2 | c.75G>A p.G25= | Silent (SNP) | VAF 69/368 reads (19%) | catalogued as COSV59991788, COSV59992521; called by muse, mutect2, varscan2
- GRIK4 | c.2457C>A p.A819= | Silent (SNP) | VAF 38/304 reads (13%) | called by muse, mutect2, varscan2
- GUCY2F | c.1224C>A p.I408= | Silent (SNP) | VAF 48/320 reads (15%) | catalogued as rs765819769; called by muse, varscan2
- HECW2 | c.1641A>G p.P547= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs148661272; called by muse, mutect2, varscan2
- HEPH | c.3435C>A p.S1145= (on ENST00000343002; = p.S878= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/260 reads (17%) | called by muse, mutect2, varscan2
- HPX | c.576G>T p.L192= | Silent (SNP) | VAF 103/605 reads (17%) | called by muse, mutect2, varscan2
- HTR3B | c.81C>A p.P27= | Silent (SNP) | VAF 43/313 reads (14%) | called by muse, mutect2, varscan2
- HYDIN | c.447T>C p.D149= | Silent (SNP) | VAF 39/245 reads (16%) | called by muse, mutect2, varscan2
- IDS | c.174G>T p.L58= | Silent (SNP) | VAF 89/577 reads (15%) | called by muse, mutect2, varscan2
- IQSEC2 | c.1482C>A p.A494= (on ENST00000642864 / NM_001111125.3; = p.A289= on NM_015075.2) | Silent (SNP) | VAF 114/518 reads (22%) | called by muse, mutect2, varscan2
- KCNF1 | c.1146G>T p.L382= | Silent (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- KCNU1 | c.3114C>A p.P1038= | Silent (SNP) | VAF 92/162 reads (57%) | called by muse, mutect2, varscan2
- KHNYN | c.552G>C p.L184= | Silent (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.1029T>A p.I343= | Silent (SNP) | VAF 54/422 reads (13%) | called by muse, varscan2
- KRT6B | c.69C>A p.A23= | Silent (SNP) | VAF 146/817 reads (18%) | called by muse, mutect2, varscan2
- KRTAP9-7 | c.474C>A p.T158= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs747515749; called by muse, mutect2, varscan2
- L1CAM | c.1800G>A p.V600= | Silent (SNP) | VAF 80/412 reads (19%) | called by muse, mutect2, varscan2
- LRRC23 | c.426T>A p.A142= | Silent (SNP) | VAF 88/484 reads (18%) | catalogued as rs1364082585; called by muse, mutect2, varscan2
- LRRC32 | c.1492C>T p.L498= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as rs547340312; called by muse, mutect2, varscan2
- LRRC4C | c.180G>A p.V60= | Silent (SNP) | VAF 41/262 reads (16%) | called by muse, mutect2, varscan2
- LRRK2 | c.1068A>G p.A356= | Silent (SNP) | VAF 35/300 reads (12%) | called by muse, mutect2, varscan2
- MAGEC1 | c.3282C>T p.T1094= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as rs771850104, COSV53576412, COSV53580076; called by muse, varscan2
- MCTS1 | c.357T>A p.P119= | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- MED12 | c.5808C>T p.Y1936= | Silent (SNP) | VAF 63/385 reads (16%) | catalogued as rs757398839; called by muse, mutect2, varscan2
- MERTK | c.570C>T p.Y190= | Silent (SNP) | VAF 112/492 reads (23%) | catalogued as rs768197648, COSV54928395; called by muse, mutect2, varscan2
- MMP26 | c.279G>A p.S93= | Silent (SNP) | VAF 48/229 reads (21%) | catalogued as rs149405690; called by muse, mutect2, varscan2
- MRM1 | c.663G>C p.V221= | Silent (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- MSR1 | c.672A>T p.A224= | Silent (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- NDUFV1 | c.1362C>T p.A454= | Silent (SNP) | VAF 82/436 reads (19%) | called by muse, mutect2, varscan2
- NKD2 | c.1131G>A p.P377= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs908137517; called by muse, mutect2, varscan2
- NOL12 | c.279G>A p.T93= | Silent (SNP) | VAF 82/397 reads (21%) | catalogued as rs753142556, COSV63031055; called by muse, mutect2, varscan2
- NOL4L | c.610C>T p.L204= | Silent (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- NUP188 | c.123G>T p.R41= | Silent (SNP) | VAF 77/436 reads (18%) | called by muse, varscan2
- OR10A2 | c.819C>T p.N273= | Silent (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- OR5L1 | c.750C>T p.V250= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as COSV100450150; called by muse, mutect2, varscan2
- OTOGL | c.1407T>A p.G469= (on ENST00000547103; = p.G460= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, varscan2
- P2RY8 | c.75C>A p.A25= | Silent (SNP) | VAF 48/251 reads (19%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2292C>A p.P764= | Silent (SNP) | VAF 129/495 reads (26%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1722T>A p.G574= | Silent (SNP) | VAF 130/506 reads (26%) | called by muse, mutect2, varscan2
- PFKFB1 | c.927C>A p.T309= | Silent (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- PIKFYVE | c.6066G>T p.G2022= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- PKD1 | c.8820C>G p.P2940= | Silent (SNP) | VAF 89/359 reads (25%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4476C>T p.R1492= | Silent (SNP) | VAF 108/330 reads (33%) | called by muse, mutect2, varscan2
- PTPRO | c.2487T>A p.L829= | Silent (SNP) | VAF 55/318 reads (17%) | catalogued as COSV55511186; called by muse, mutect2, varscan2
- REG3A | c.504C>A p.P168= | Silent (SNP) | VAF 67/394 reads (17%) | called by muse, mutect2, varscan2
- RFX6 | c.1791A>T p.T597= | Silent (SNP) | VAF 93/524 reads (18%) | called by muse, mutect2, varscan2
- RFX7 | c.3306A>T p.P1102= (on ENST00000559447 / NM_001368074.1; = p.P1199= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/257 reads (21%) | called by muse, mutect2, varscan2
- RIMS1 | c.42G>T p.T14= | Silent (SNP) | VAF 43/224 reads (19%) | called by muse, mutect2, varscan2
- SCLT1 | c.2034A>G p.K678= | Silent (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- SELENOT | c.372T>C p.N124= | Silent (SNP) | VAF 20/150 reads (13%) | called by muse, varscan2
- SIPA1L1 | c.4941G>T p.S1647= | Silent (SNP) | VAF 62/266 reads (23%) | catalogued as COSV100665802; called by muse, mutect2, varscan2
- SLC18A3 | c.243C>G p.T81= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- SLC18B1 | c.393T>C p.A131= | Silent (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- SLC25A26 | c.537T>C p.S179= | Silent (SNP) | VAF 41/240 reads (17%) | called by muse, mutect2, varscan2
- SLIT3 | c.2487C>A p.T829= | Silent (SNP) | VAF 76/385 reads (20%) | catalogued as rs557486742; called by muse, mutect2, varscan2
- SPDEF | c.750C>T p.H250= | Silent (SNP) | VAF 86/387 reads (22%) | called by muse, mutect2, varscan2
- STT3B | c.1086T>G p.G362= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- SUGP2 | c.3090G>T p.L1030= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- TCP11 | c.420G>T p.L140= (on ENST00000512012; = p.L78= on NM_018679.5) | Silent (SNP) | VAF 56/352 reads (16%) | called by muse, mutect2, varscan2
- TENM1 | c.7498C>A p.R2500= | Silent (SNP) | VAF 44/256 reads (17%) | called by muse, mutect2, varscan2
- TENM3 | c.6867G>T p.G2289= | Silent (SNP) | VAF 63/236 reads (27%) | called by muse, mutect2, varscan2
- TMEM236 | c.168C>T p.A56= | Silent (SNP) | VAF 138/766 reads (18%) | called by muse, mutect2, varscan2
- TMEM30A | c.108A>G p.Q36= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs981992858; called by muse, varscan2
- TPTE2 | c.537A>G p.L179= (on ENST00000400230 / NM_199254.2; = p.L102= on NM_130785.3) | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, varscan2
- TRGV8 | c.33C>T p.F11= | Silent (SNP) | VAF 48/317 reads (15%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.468G>T p.P156= | Silent (SNP) | VAF 101/274 reads (37%) | called by muse, mutect2, varscan2
- UPRT | c.147G>C p.V49= | Silent (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- USP17L2 | c.1179C>A p.A393= | Silent (SNP) | VAF 194/1634 reads (12%) | catalogued as rs548079218; called by mutect2, varscan2
- ZBTB38 | c.2688C>T p.C896= | Silent (SNP) | VAF 54/281 reads (19%) | called by muse, mutect2, varscan2
- ZIC1 | c.660C>A p.P220= | Silent (SNP) | VAF 44/279 reads (16%) | called by muse, mutect2, varscan2
- ZNF33B | c.1224A>T p.T408= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- ZNF516 | c.2190C>T p.L730= | Silent (SNP) | VAF 62/269 reads (23%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.390G>T p.A130= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1319683900; called by muse, varscan2
- AC008758.3 | n.920C>T | RNA (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- AC079154.1 | n.979G>C | RNA (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9721T>C | Intron (SNP) | VAF 51/211 reads (24%) | catalogued as COSV73145020; called by muse, mutect2, varscan2
- ACP7 | c.692+9G>T | Intron (SNP) | VAF 32/278 reads (12%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.833del | RNA (DEL) | VAF 33/213 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.-40C>A | 5'UTR (SNP) | VAF 18/113 reads (16%) | catalogued as rs904153330; called by muse, mutect2, varscan2
- AGPAT4 | c.348+4948C>T | Intron (SNP) | VAF 29/170 reads (17%) | catalogued as rs1225701776; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824176 G>T | 5'Flank (SNP) | VAF 33/218 reads (15%) | called by muse, mutect2, varscan2
- AP000679.1 | n.731T>C | RNA (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- APBA2 | c.2037+30A>T | Intron (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2
- ARFGAP1 | c.834+322G>T | Intron (SNP) | VAF 26/77 reads (34%) | catalogued as rs550316497, COSV62263132; called by muse, mutect2, varscan2
- BSCL2 | c.813+9G>C | Intron (SNP) | VAF 46/208 reads (22%) | called by muse, mutect2, varscan2
- CEP57 | c.46-3684A>G | Intron (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100334726; called by muse, varscan2
- CMSS1 | c.65-32021G>T | Intron (SNP) | VAF 55/331 reads (17%) | called by muse, mutect2, varscan2
- CPA4 | c.68+61G>C | Intron (SNP) | VAF 50/164 reads (30%) | called by muse, mutect2, varscan2
- CRTC1 | c.-8G>T | 5'UTR (SNP) | VAF 17/102 reads (17%) | called by muse, varscan2
- DENND10P1 | n.320G>T | RNA (SNP) | VAF 124/818 reads (15%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.*54T>C | 3'UTR (SNP) | VAF 34/206 reads (17%) | called by muse, varscan2
- EMB | c.*17_*18insT | 3'UTR (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel*, varscan2
- FAM138C | n.341G>A | RNA (SNP) | VAF 19/62 reads (31%) | called by mutect2, varscan2
- FLT4 | c.3538-29G>T | Intron (SNP) | VAF 41/153 reads (27%) | catalogued as rs746765230; called by muse, mutect2, varscan2
- GABRB3 | c.*3G>T | 3'UTR (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- H2AZ2 | chr7:44830133 C>A | 3'Flank (SNP) | VAF 27/218 reads (12%) | catalogued as rs763128803; called by muse, varscan2
- HNRNPLL | c.803-411G>A | Intron (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- HOXB6 | c.-79+2269G>A | Intron (SNP) | VAF 57/387 reads (15%) | called by muse, mutect2, varscan2
- ICA1 | c.804+108G>A | Intron (SNP) | VAF 70/435 reads (16%) | called by muse, mutect2, varscan2
- IDO2 | c.435-30G>T | Intron (SNP) | VAF 26/122 reads (21%) | catalogued as rs773414321; called by muse, mutect2, varscan2
- KLHL4 | c.*2792C>A | 3'UTR (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- LINC00934 | n.1435-29A>G | Intron (SNP) | VAF 38/254 reads (15%) | called by muse, mutect2, varscan2
- LINC02756 | n.311+7329A>T | Intron (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- MANBA | c.1455+38A>G | Intron (SNP) | VAF 51/242 reads (21%) | catalogued as rs778757800; called by muse, mutect2, varscan2
- MASP2 | c.544+124C>A | Intron (SNP) | VAF 35/158 reads (22%) | called by muse, mutect2, varscan2
- MAX | c.172-6260T>C | Intron (SNP) | VAF 36/285 reads (13%) | called by muse, varscan2
- MIR29B2CHG | n.349G>A | RNA (SNP) | VAF 86/355 reads (24%) | called by muse, mutect2, varscan2
- MIR513C | n.72G>T | RNA (SNP) | VAF 56/411 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.16137-19C>A | Intron (SNP) | VAF 29/166 reads (17%) | called by muse, mutect2, varscan2
- MYO3B | c.3575+5056G>T | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- NMNAT2 | c.86-10949T>A | Intron (SNP) | VAF 58/307 reads (19%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1759G>T | RNA (SNP) | VAF 68/365 reads (19%) | called by muse, mutect2, varscan2
- NR2C1 | c.1393+503A>G | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, varscan2
- OPRM1 | c.-13G>T | 5'UTR (SNP) | VAF 54/389 reads (14%) | catalogued as COSV57684681; called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53307C>T | Intron (SNP) | VAF 71/425 reads (17%) | called by muse, mutect2, varscan2
- OTOGL | c.6268-262T>C | Intron (SNP) | VAF 27/131 reads (21%) | catalogued as rs1454820639; called by muse, mutect2, varscan2
- P3H3 | c.1333+15G>T | Intron (SNP) | VAF 63/262 reads (24%) | called by muse, mutect2, varscan2
- PDE6G | c.*554C>T | 3'UTR (SNP) | VAF 46/193 reads (24%) | called by muse, mutect2, varscan2
- PGRMC1 | c.-37C>A | 5'UTR (SNP) | VAF 50/356 reads (14%) | catalogued as rs776493719; called by muse, mutect2, varscan2
- PPP1R18 | c.*181A>C | 3'UTR (SNP) | VAF 42/196 reads (21%) | called by mutect2, varscan2
- PRECSIT | n.595C>A | RNA (SNP) | VAF 58/299 reads (19%) | called by muse, mutect2, varscan2
- PSRC1 | c.-5T>A | 5'UTR (SNP) | VAF 84/467 reads (18%) | called by muse, mutect2, varscan2
- RAD51D | c.*88G>T | 3'UTR (SNP) | VAF 78/456 reads (17%) | called by muse, mutect2, varscan2
- RAE1 | c.1020+50C>A | Intron (SNP) | VAF 106/403 reads (26%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158865 C>A | 5'Flank (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158866 C>A | 5'Flank (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- RPL13A | chr19:49487535 C>T | 5'Flank (SNP) | VAF 28/168 reads (17%) | catalogued as rs562307401; called by muse, mutect2, varscan2
- SCIN | c.517-8089A>T | Intron (SNP) | VAF 52/298 reads (17%) | called by muse, mutect2, varscan2
- SCMH1 | c.-433G>C | 5'UTR (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- SDHAF2 | c.370+20G>A | Intron (SNP) | VAF 66/366 reads (18%) | called by muse, mutect2, varscan2
- SLC16A6P1 | n.582C>T | RNA (SNP) | VAF 102/702 reads (15%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1915+543C>A | Intron (SNP) | VAF 44/240 reads (18%) | called by muse, varscan2
- SMARCA1 | c.*93A>G | 3'UTR (SNP) | VAF 26/168 reads (15%) | called by muse, varscan2
- SNORA71B | n.44G>T | RNA (SNP) | VAF 54/248 reads (22%) | called by muse, mutect2, varscan2
- SNORD115-16 | n.3G>T | RNA (SNP) | VAF 48/367 reads (13%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210162331 G>T | 3'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- TAZ | c.284+27G>T | Intron (SNP) | VAF 87/500 reads (17%) | called by muse, mutect2, varscan2
- TKTL1 | c.1402-212G>T | Intron (SNP) | VAF 62/402 reads (15%) | catalogued as COSV54214781; called by muse, mutect2, varscan2
- TMEM255A | c.424-194G>C | Intron (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2
- TMPRSS15 | c.*28C>T | 3'UTR (SNP) | VAF 31/142 reads (22%) | catalogued as rs774703212; called by muse, mutect2, varscan2
- TSHR | c.692+242C>A | Intron (SNP) | VAF 129/646 reads (20%) | called by muse, mutect2, varscan2
- UBBP4 | n.452C>A | RNA (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- USP14 | c.-96C>T | 5'UTR (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- VAPB | c.*4714G>T | 3'UTR (SNP) | VAF 123/559 reads (22%) | called by muse, mutect2, varscan2
- XIAP | c.*179G>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- ZC3H14 | c.1280-1679C>T | Intron (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+3962A>T | Intron (SNP) | VAF 34/205 reads (17%) | called by muse, mutect2, varscan2
- ZNF767P | n.265del | RNA (DEL) | VAF 61/434 reads (14%) | called by mutect2, varscan2
- ZNF849P | n.749G>C | RNA (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- ZNF971P | n.991C>G | RNA (SNP) | VAF 43/304 reads (14%) | called by muse, mutect2, varscan2
